Somatic mutation profile of tumor specimen MP2PRT-PAPIJB-TMP1-A (aliquot MP2PRT-PAPIJB-TMP1-A-1-0-D-A83C-36) from MP2PRT case MP2PRT-PAPIJB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,005 days).
Specimen MP2PRT-PAPIJB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20e12897-7ee1-4d36-ac1b-27550d081cad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPIJB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPIJB-NB1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/464b02f8-7485-4964-a6c4-3f6cbbf622e0

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, Nonsense Mutation 2, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.3836+1G>A p.X1279_splice | Splice Site (SNP) | VAF 39/152 reads (26%) | catalogued as rs200782888, CS056749, COSV52117332; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 20/278 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 44/244 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASB4 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 39/423 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV57943147; called by muse, mutect2
- EFCAB3 | c.126G>T p.K42N | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV100540028; called by muse, mutect2, varscan2
- ELOVL2 | c.400G>C p.V134L | Missense Mutation (SNP) | VAF 25/336 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV61154120; called by muse, mutect2
- GATA6 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 74/699 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs769197296; called by muse, mutect2, varscan2
- KDM3B | c.2302G>A p.V768I | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs147174917; called by muse, mutect2
- MAGI3 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 32/334 reads (10%) | catalogued as rs1370263133, COSV56833761; called by muse, mutect2
- MIB2 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 110/355 reads (31%) | catalogued as rs748579075, COSV61755718; called by muse, mutect2, varscan2
- PTPN21 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 62/400 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1225029657; called by muse, mutect2, varscan2
- RBMXL3 | c.1756G>A p.G586R | Missense Mutation (SNP) | VAF 24/546 reads (4%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs782358096; called by muse, mutect2
- SERPINB3 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 72/386 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs577262694; called by muse, mutect2, varscan2
- SLC35F1 | c.1118C>A p.P373H | Missense Mutation (SNP) | VAF 74/457 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100838146; called by muse, mutect2, varscan2
- ABCA10 | c.2357T>A p.I786N | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); called by muse, mutect2
- CCNB3 | c.1068C>A p.N356K | Missense Mutation (SNP) | VAF 93/387 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- KIF5A | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MAP3K15 | c.385_386del p.D129Cfs*18 | Frame Shift Del (DEL) | VAF 36/187 reads (19%) | called by mutect2, pindel, varscan2
- MYO7B | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT tolerated (0.75); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PTPRQ | c.6947del p.L2316Wfs*75 (on ENST00000616559; = p.L2283Wfs*75 on NM_001145026.2) | Frame Shift Del (DEL) | VAF 21/186 reads (11%) | called by mutect2, pindel, varscan2
- TSPYL1 | c.1252_1253insCCCAC p.R418Pfs*7 | Frame Shift Ins (INS) | VAF 44/268 reads (16%) | called by mutect2, pindel, varscan2
- ZNF717 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 10/254 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2
- CD22 | c.2004C>T p.G668= | Silent (SNP) | VAF 35/335 reads (10%) | catalogued as COSV50069922; called by muse, mutect2, varscan2
- OR2B3 | c.639G>A p.L213= | Silent (SNP) | VAF 38/590 reads (6%) | catalogued as COSV65850818, COSV65850822; called by muse, mutect2
- PCDHA12 | c.1854G>A p.A618= | Silent (SNP) | VAF 32/408 reads (8%) | called by muse, mutect2
- THEMIS | c.1206G>A p.E402= | Silent (SNP) | VAF 88/497 reads (18%) | catalogued as rs767437602; called by muse, mutect2, varscan2
- MAPK8IP2 | c.172-22G>T | Intron (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2, varscan2
